CCDI case PBCFMA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f4b8c0ea-1941-4523-b27e-973c188bd549

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Ependymoma, anaplastic: ICD-O-3 morphology code: 9392/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 0.8 years (293 days).

Biospecimens (2 samples)
- Sample 0DRGEG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRGF1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
